Surgical pathology report (de-identified scan), TCGA case TCGA-SI-A71P, project TCGA-SARC (Sarcoma), tissue source site Washington University St. Louis, specimen TCGA-SI-A71P-01A (Primary Tumor).

[page 1 of 5]
Patient Name: [REDACTED]

DOB: [REDACTED]

MRN: [REDACTED]
Patient [REDACTED]

Surgical Pathology Report

Final

ICD-O-3

Tumor peripheral nerve
sheath malignant 9540/3

Site =
Site 4 Brachial plexus
047.1

path
Spinal cord nerve NOS
047.9

JW 8/9/13

SURGICAL PATHOLOGY REPORT FINAL

Patient Name: [REDACTED]

Address: [REDACTED]

Service: [REDACTED]

Location: [REDACTED]

Accession #: [REDACTED]

Taken: [REDACTED]

Gender: [REDACTED]

DOB: [REDACTED]

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type: [REDACTED]

Received: [REDACTED]

Accession #: [REDACTED]

Reported: [REDACTED]

Physician(s): [REDACTED]

DIAGNOSIS:

SPINAL CORD, "RIGHT S4 NERVE ROOT," BIOPSY (INCLUDES FS1A AND FS1B) (A)
-PLEXIFORM NEUROFIBROMA (SEE COMMENT)

SPINAL CORD, "LEFT S4 NERVE ROOT," BIOPSY (INCLUDES FS2A AND FS2B) (B)
-FOCUS SUSPICIOUS FOR MALIGNANT PERIPHERAL NERVE SHEATH TUMOR
-PLEXIFORM NEUROFIBROMA (SEE COMMENT)

SPINAL CORD, "RIGHT S3 NERVE ROOT," BIOPSY (INCLUDES FS3) (C)
-MALIGNANT PERIPHERAL NERVE SHEATH TUMOR
-PLEXIFORM NEUROFIBROMA (SEE COMMENT)

SPINAL CORD, "LEFT S3 NERVE ROOT," BIOPSY (INCLUDES FS4) (D)
-MALIGNANT PERIPHERAL NERVE SHEATH TUMOR
-PLEXIFORM NEUROFIBROMA (SEE COMMENT)

SPINAL CORD, "RIGHT S2 NERVE ROOT," BIOPSY (INCLUDES FS5) (E)
-MALIGNANT PERIPHERAL NERVE SHEATH TUMOR
-PLEXIFORM NEUROFIBROMA (SEE COMMENT)

SPINAL CORD, "LEFT S2 NERVE ROOT," BIOPSY (INCLUDES FS6A AND FS6B) (F)
-PLEXIFORM NEUROFIBROMA (SEE COMMENT)

SPINAL CORD, "LEFT S1 NERVE ROOT," BIOPSY (INCLUDES FS7) (G)
-MALIGNANT PERIPHERAL NERVE SHEATH TUMOR
-PLEXIFORM NEUROFIBROMA (SEE COMMENT)

SPINAL CORD, "RIGHT S1 NERVE ROOT," BIOPSY (INCLUDES FS8) (H)
-MALIGNANT PERIPHERAL NERVE SHEATH TUMOR
-PLEXIFORM NEUROFIBROMA (SEE COMMENT)

SOFT TISSUE AND BONE, "SACRAL MASS," EXCISION (I)
-MALIGNANT PERIPHERAL NERVE SHEATH TUMOR
-PLEXIFORM NEUROFIBROMA (SEE COMMENT)

SPINAL CORD, "RIGHT S2 NERVE ROOT," BIOPSY (J)

[page 2 of 5]
Patient Name: [REDACTED]

DOB: [REDACTED]

MRN: [REDACTED]

Patient ID: [REDACTED]

SURGICAL PATHOLOGY REPORT

- MALIGNANT PERIPHERAL NERVE SHEATH TUMOR
- PLEXIFORM NEUROFIBROMA (SEE COMMENT)

SPINAL CORD, "LEFT S2 NERVE ROOT," BIOPSY (K)

- MALIGNANT PERIPHERAL NERVE SHEATH TUMOR
- PLEXIFORM NEUROFIBROMA (SEE COMMENT)

SPINAL CORD, "RIGHT S3 NERVE ROOT," BIOPSY (L)

- PLEXIFORM NEUROFIBROMA (SEE COMMENT)

SPINAL CORD, "LEFT S3 NERVE ROOT," BIOPSY (M)

- MALIGNANT PERIPHERAL NERVE SHEATH TUMOR
- PLEXIFORM NEUROFIBROMA (SEE COMMENT)

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides and/or other material indicated in the diagnosis.

***Report Electronically Reviewed and Signed Out.

Intraoperative Consultation:

An intraoperative consultation was obtained. Multiple specimens (designated below) were picked up / delivered from the operating room for intraoperative consultation:

FS1A and B: Right S4 nerve root

- "Spindle cell neoplasm, favor neurofibroma," by

FS2A and B: Left S4 nerve root

- "Spindle cell neoplasm, favor neurofibroma," by

FS3: Right S3 nerve root

- "High grade neoplasm, morphologically consistent with 'pleomorphic sarcoma' [REDACTED], " by

FS4: Left S3 nerve root

- "High grade neoplasm, morphologically consistent with 'pleomorphic sarcoma' [REDACTED] " by

FS5: Right S2 nerve root

- "High grade neoplasm, morphologically consistent with 'pleomorphic sarcoma' [REDACTED] by

FS6A and B: Left S2 nerve root

- "Focally suspicious for high grade neoplasm," by

FS7: Left S1 nerve root

- "High grade neoplasm, morphologically consistent with 'pleomorphic sarcoma' [REDACTED] by

FS8: Right S1 nerve root

- "High grade neoplasm, morphologically consistent with 'pleomorphic sarcoma' [REDACTED] b

[page 3 of 5]
Patient Name: [REDACTED]

DOB: [REDACTED]

MRN: [REDACTED]

Patient ID: [REDACTED]

SURGICAL PATHOLOGY REPORT

Microscopic Description and Comment:

Histological sections of specimens A through M show two histological patterns of neoplasia. One pattern, representing neurofibroma and present within all the specimens included in this case, is generally modestly cellular; its wavy spindled cells with oval to elongated nuclei show only very rare mitotic activity and appear within a variably edematous/myxoid background of wavy collagen fibrils. In specimen K, the neurofibroma tissue exhibits increased cellularity.

The second histological pattern is formed by a markedly pleomorphic and highly proliferative cell population with many areas of necrosis. The cells range from smaller spindled forms to large, irregular epithelioid cells with one or more strikingly pleomorphic nuclei, coarse chromatin, occasional nuclear pseudoinclusions, prominent nucleoli, and variably eosinophilic or amphophilic cytoplasm. Sections from the "sacral mass" (specimen I) show evidence of bone and soft tissue invasion by the malignant tumor tissue, accompanied by lytic and remodeling changes in the bone.

The malignant pattern involves the left S3 nerve root (specimens D and M), the right S2 nerve root (specimens E and J), and the left and right S1 nerve roots (specimens G and H) in both the material submitted for frozen sections as well as 'permanent' sections.

The malignant pattern is also observed in the left S2 nerve root specimen sent for permanents (specimen K) but not in the left S2 nerve root specimen sent for frozen sections (specimen F).

The malignant pattern is also identified in the right S3 nerve root specimen taken for frozen sections (specimen C) but not in the right S3 nerve root specimen that was subsequently submitted for 'permanent' sections (specimen L).

A minute focus of tissue suspicious for malignancy but with significant crush artifact is identified on the 'permanent' sections prepared from the left S4 nerve root (specimen B).

No evidence of malignant tissue is identified in the right S4 nerve root (specimen A).

Immunohistochemically stained sections of the malignant tissue (block I1) show only weak reactivity for S100 within few scattered cells. Reactivity for Collagen IV stains the periphery (basal lamina) of tumor cells with a patchy distribution within the tissue. Reactivity for CD57 (Leu7) within the malignant tumor tissue is likewise observed within focal regions.

Strong reactivity for p53 in >90% of the malignant cell nuclei and strong reactivity for vimentin were demonstrated previously on the material from the patient's prior needle biopsy specimen [REDACTED].

Comment:

Within the clinical and radiological context of this case, the histomorphological and immunohistochemical features of these specimens (and of the patient's prior biopsy specimen [REDACTED]) collectively describe a malignant peripheral nerve sheath tumor (MPNST) arising within a plexiform neurofibroma. Histologically, this MPNST resembles the epithelioid subtype of MPNST, but with marked pleomorphism and anaplastic features.

[REDACTED] is reviewed selected slides from this case and agrees with the diagnosis.

History:

The patient is a [REDACTED] year-old man, with personal and family history of neurofibromatosis type I, who has had increasing difficulty with initiating micturition and maintaining bowel control. He also developed a sore in the gluteal cleft and has noticed that his entire buttocks have become insensate. Among numerous subcutaneous, deep, and nerve-root associated neurofibromas, MRI and PET imaging studies identified an FDG avid soft tissue mass that fills the central canal from L5 to S4, invades and remodels the S2 and S3 vertebral bodies, has destroyed the posterior elements from

[page 4 of 5]
Patient Name: [REDACTED]

DOB: [REDACTED]

MRN: [REDACTED]

Patient ID: [REDACTED]

SURGICAL PATHOLOGY REPORT

L5 to S2, and extends into the paraspinal musculature. Radiological impression: Suspicious for malignant degeneration of a plexiform neurofibroma. A needle biopsy of the sacral mass yielded the diagnosis 'pleomorphic sarcoma,' with a comment that the lesion is suggestive of malignant peripheral nerve sheath tumor.

Operative procedure: Excision of sacral mass.

Specimen(s) Received:

A: RIGHT S4 NERVE ROOT
B: LEFT S4 NERVE ROOT
C: RIGHT S3 NERVE ROOT
D: LEFT S3 NERVE ROOT
E: RIGHT S2 NERVE ROOT
F: LEFT S2 NERVE ROOT
G: LEFT S1 NERVE ROOT
H: RIGHT S1 NERVE ROOT
I: SACRAL MASS
J: RIGHT S2 NERVE ROOT PERMANENT
K: LEFT S2 NERVE ROOT PERMANENT
L: RIGHT S3 NERVE ROOT PERMANENT
M: LEFT S3 NERVE ROOT PERMANENT

Gross Description:

Received are thirteen formalin-filled containers, each labeled [REDACTED]. The first container is additionally labeled "right S4 nerve root (FS1/X)." It holds two tissue cassettes containing frozen section remnants. The first, designated "FS1A," measures 0.9 x 0.6 x 0.2 cm. The second, designated "FS1B," measures 1.5 x 1.3 x 0.2 cm. Also present in the container is an additional fragment of tan-pink tissue measuring 1.5 x 0.9 x 0.2 cm. Labeled A1 (FS1A); A2 (FS1B); A3 - additional fragment. Jar 0.

The second container is additionally labeled "left S4 nerve root (FS2A and B)." It holds two tissue cassettes containing frozen section remnants. The first, designated "FS2A," measures 1.3 x 1.0 x 0.2 cm. The second, designated "FS2B," measures 0.7 x 0.3 x 0.2 cm. Also present in the container are two additional fragments of pink-tan tissue measuring 1.2 x 1.0 x 0.7 cm and 1.1 x 1.0 x 0.2 cm. Labeled B1 (FS2A); B2 (FS2B); B3 - additional fragments of tissue. Jar 0.

The third container is additionally labeled "right S3 nerve root (FS3/X)." It holds a tissue cassette that contains a frozen section remnant, designated "FS3," that measures 1.1 x 0.5 x 0.2 cm. Also present in the container is an additional fragment of tan-pink tissue measuring 1.2 x 1.1 x 0.3 cm. Labeled C1 (FS3); C2 - additional fragment. Jar 0.

The fourth container is additionally labeled "L S3 nerve root (FS4/X)." It holds a tissue cassette that contains a frozen section remnant, designated "FS4," that measures 1.0 x 0.5 x 0.1 cm. Also present in the container is an additional fragment of tan-pink tissue measuring 1.7 x 1.2 x 0.3 cm. Labeled D1 (FS4); D2 - additional fragment. Jar 0.

The fifth container is additionally labeled "right S2 nerve root (FS5/X)." It holds a tissue cassette that contains a frozen section remnant, designated "FS5," that measures 0.7 x 0.3 x 0.1 cm. Also present is an additional fragment of tan-pink tissue measuring 1.7 x 0.9 x 0.3 cm. Labeled E1 (FS5); E2 - additional fragment. Jar 0.

The sixth container is additionally labeled "L S2 nerve root (FS6/X)." It holds two tissue cassettes containing frozen section remnants. The first, designated "FS6A," measures 1.1 x 0.5 x 0.1 cm. The second, designated "FS6B," measures 1.5 x 0.9 x 0.4 cm. Also present is additional tan-pink tissue measuring 1.5 x 0.7 x 0.3 cm. Labeled F1 (FS6); F2 (FS6B); F3 - additional tissue. Jar 0.

The seventh container is additionally labeled "left S1 nerve root (FS7/X)." It holds a tissue cassette that contains a frozen section remnant, designated "FS7," that measures 1.5 x 1.2 x 0.1 cm. Also present is pink-tan tissue measuring 1.4 x 1.2 x 0.5 cm. Labeled G1 (FS7); G2 - additional tissue. Jar 0.

The eighth container is additionally labeled "right S1 nerve root (FS8/X)." It holds a tissue cassette that contains a frozen section remnant, designated "FS8," that measures 1.5 x 0.6 x 0.1 cm. Also present in the container is an additional fragment of tan-pink tissue measuring 1.5 x 1.5 x 0.3 cm. Labeled H1 (FS8); H2 - additional fragment. Jar 0.

The ninth container is additionally labeled "sacral mass." It holds multiple fragments of red-pink tissue measuring 13.5

[page 5 of 5]
Patient Name: [REDACTED]

DOB: [REDACTED]

MRN: [REDACTED]

Patient: [REDACTED]

SURGICAL PATHOLOGY REPORT

x 9.2 x 4 cm in aggregate. Necrosis is evident. Sectioned to show a portion of tan-brown bone measuring 5 x 2.2 x 1.9 cm. Labeled I1 to I14. Acid decalcification. Jar 2.

The tenth container is additionally labeled "right S2 nerve root permanent." It holds a fragment of tan-brown tissue measuring 1.5 x 1.4 x 0.5 cm. Bisected. Labeled J1. Jar 0.

The 11th container is additionally labeled "left S2 nerve root permanent." It holds a fragment of tan-brown tissue measuring 1.5 x 1.2 x 0.9 cm. Bisected. Labeled K1. Jar 0.

The 12th container is additionally labeled "right S3 nerve root permanent." It holds a fragment of tan-brown tissue measuring 1.6 x 1 x 0.8 cm. Bisected. Labeled L1. Jar 0.

The 13th container is additionally labeled "left S3 nerve root permanent." It holds a fragment of tan-white tissue measuring 1 x 1 x 1.1 cm. Bisected. Labeled M1. Jar 0.

Surgical Pathology report is available on-line at

END OF REPORT

Page 5 of 5

Page: 5 of 5

Printed from

Criteria	ju 7/26/13	Yes	No
Diagnosis Discrepancy	by TSS -		
Primary Tumor Site Discrepancy	Brachial Plexus		
IHPAA Discrepancy			
Dual/Synchronous Primary	Noted		
TSS verified Left Brachial Plexus			

Source: NCI Genomic Data Commons file 75ea3aea-228a-416f-82b9-70cd202f5180 (TCGA-SI-A71P.5EF5CAAB-74FF-436F-9316-2352E239A51A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).